Somatic mutation profile of tumor specimen C3L-06207-02 (aliquot CPT0424840006) from CPTAC case C3L-06207, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 64.3 years (23,484 days).
Specimen C3L-06207-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ea86518-b17b-4ee6-b3cd-3bef4ee14344.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06207-32 (Blood Derived Normal), aliquot CPT0424950005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/751429e2-0fac-4af3-b323-cf2c5a89c4fa

The open-access MAF lists 1,511 somatic variants for this specimen: 955 protein-altering or splice-affecting, 498 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 860, Silent 498, Nonsense Mutation 71, Intron 32, Splice Region 12, 3'UTR 9, Splice Site 7, 3'Flank 6, RNA 4, 5'Flank 4, 5'UTR 3, Frame Shift Del 2.

Variants (750 of 1,511; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 42/606 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913386, CM983988, COSV58683051, COSV58690307, COSV58692178; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- MC4R | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 44/685 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs121913567, CM050063; ClinVar: pathogenic; called by muse, mutect2
- A1CF | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV99256102; called by muse, mutect2, varscan2
- ABCA13 | c.14704G>A p.E4902K | Missense Mutation (SNP) | VAF 104/555 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs765360658; called by muse, mutect2, varscan2
- ABCB11 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.851); catalogued as rs1425176717; called by muse, mutect2, varscan2
- ABCC6 | c.3733G>A p.E1245K | Missense Mutation (SNP) | VAF 92/353 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52743319; called by muse, mutect2, varscan2
- ACAN | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 147/665 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100718074; called by muse, mutect2, varscan2
- ACE2 | c.1694C>T p.P565L | Missense Mutation (SNP) | VAF 124/463 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV53023427; called by muse, mutect2, varscan2
- ACSM2A | c.1189G>A p.D397N (on ENST00000219054; = p.D318N on NM_001308169.2) | Missense Mutation (SNP) | VAF 98/325 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs750637232, COSV54582503; called by muse, mutect2, varscan2
- ACTC1 | c.278A>T p.Y93F | Missense Mutation (SNP) | VAF 90/457 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.597); catalogued as COSV51758685; called by muse, varscan2
- ACTL7B | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 36/518 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as rs11543180; called by muse, mutect2
- ADAD1 | c.1505G>T p.G502V | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371027816; called by mutect2, varscan2
- ADAM29 | c.1241G>A p.G414E | Missense Mutation (SNP) | VAF 80/592 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63666852; called by muse, mutect2, varscan2
- ADCY8 | c.1631G>A p.G544E | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53901383; called by muse, mutect2, varscan2
- ADGRV1 | c.4664C>T p.S1555L | Missense Mutation (SNP) | VAF 77/281 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.877); catalogued as rs762055707, COSV101316026, COSV67979966; called by muse, mutect2, varscan2
- ADGRV1 | c.9115G>A p.G3039R | Missense Mutation (SNP) | VAF 77/292 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs765233729; called by muse, mutect2, varscan2
- AGR3 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 179/461 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs746862695, COSV60037702; called by muse, mutect2, varscan2
- AHCTF1 | c.1502C>T p.P501L (on ENST00000366508; = p.P475L on NM_015446.5) | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV58253611; called by muse, varscan2
- AHRR | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 33/521 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as rs775733949, COSV100327085; called by muse, mutect2
- AHSP | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 68/385 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.174); catalogued as COSV100176300; called by muse, mutect2, varscan2
- AK7 | c.847C>T p.H283Y | Missense Mutation (SNP) | VAF 36/414 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as COSV50878292; called by muse, mutect2
- AL121899.2 | c.800G>A p.R267K | Missense Mutation (SNP) | VAF 65/420 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0.014); catalogued as rs868202762, COSV101198422; called by muse, mutect2, varscan2
- AL121899.2 | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 28/443 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67351449; called by muse, mutect2
- AL645922.1 | c.1841G>A p.G614E | Missense Mutation (SNP) | VAF 86/613 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54962457; called by muse, mutect2, varscan2
- AMELX | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 124/511 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs754022687, COSV100498653, COSV61635587; called by muse, mutect2, varscan2
- AMOT | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 131/661 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.189); catalogued as rs187413230; called by muse, mutect2, varscan2
- AMY1B | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.929); catalogued as rs1189968161; called by mutect2, varscan2
- ANKRD30A | c.1007C>G p.S336C (on ENST00000611781; = p.S280C on NM_052997.2) | Missense Mutation (SNP) | VAF 51/568 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs560930371, COSV64612872; called by muse, mutect2
- ANKRD30A | c.3913G>A p.E1305K (on ENST00000611781; = p.E1249K on NM_052997.2) | Missense Mutation (SNP) | VAF 41/397 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.118); catalogued as rs867764777, COSV64614680, COSV64619316; called by muse, mutect2, varscan2
- AP3B2 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 42/336 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.082); catalogued as rs756390636; called by muse, mutect2, varscan2
- APOB | c.11374C>T p.P3792S | Missense Mutation (SNP) | VAF 138/444 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as rs767327489, COSV51936712; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF39 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 105/322 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs994417788, COSV58398109; called by muse, mutect2, varscan2
- ARID2 | c.711G>A p.W237* | Nonsense Mutation (SNP) | VAF 70/306 reads (23%) | catalogued as COSV57595446; called by muse, mutect2, varscan2
- ARL14EPL | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 100/296 reads (34%) | catalogued as rs981988957, COSV59948454, COSV59948566; called by muse, mutect2, varscan2
- ARSG | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 49/403 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1416594378; called by muse, mutect2, varscan2
- ASTN2 | c.2674G>A p.E892K (on ENST00000313400 / NM_001365069.1; = p.E841K on NM_014010.5) | Missense Mutation (SNP) | VAF 24/399 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV57775906; called by muse, mutect2
- ASTN2 | c.1567G>A p.E523K (on ENST00000313400 / NM_001365069.1; = p.E472K on NM_014010.5) | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57794282; called by muse, mutect2, varscan2
- ATP9B | c.2153C>T p.S718F | Missense Mutation (SNP) | VAF 140/511 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs1206495396; called by muse, mutect2, varscan2
- ATXN2L | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 62/543 reads (11%) | catalogued as COSV100294330, COSV57376322; called by muse, mutect2, varscan2
- BRSK1 | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 72/308 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770748082; called by muse, mutect2, varscan2
- C12orf42 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 87/308 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.208); catalogued as rs1311532483, COSV59390047; called by muse, mutect2, varscan2
- C1orf68 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 88/669 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.119); catalogued as rs971844085, COSV64224635; called by muse, mutect2, varscan2
- C4BPB | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 94/344 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs958790296; called by muse, mutect2, varscan2
- C7orf26 | c.554T>C p.V185A | Missense Mutation (SNP) | VAF 92/475 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs753059576, COSV60420007; called by muse, mutect2, varscan2
- CACNA1C | c.2896C>T p.R966W | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1053901806; called by muse, mutect2
- CAPN14 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 60/546 reads (11%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.526); catalogued as rs1157463157, COSV67292020; called by muse, mutect2, varscan2
- CAPN6 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 114/427 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60694486; called by muse, mutect2, varscan2
- CASP1 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.311); catalogued as rs372086428; called by muse, mutect2, varscan2
- CATSPERG | c.2899G>A p.E967K | Missense Mutation (SNP) | VAF 99/433 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.633); catalogued as rs147603617; called by muse, mutect2, varscan2
- CCDC160 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 17/418 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs1252711690; called by muse, mutect2
- CCDC178 | c.1313A>C p.D438A | Missense Mutation (SNP) | VAF 17/369 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV55758474; called by muse, mutect2
- CCDC197 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 114/471 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as rs944241847; called by muse, mutect2, varscan2
- CCDC198 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs1485926698, COSV53602648; called by muse, mutect2, varscan2
- CCDC8 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 152/614 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.189); catalogued as rs778774357; called by muse, mutect2, varscan2
- CCER1 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 158/642 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1405925733, COSV62646901; called by muse, varscan2
- CCNB3 | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 31/709 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs192785609; called by muse, mutect2
- CD163L1 | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 16/448 reads (4%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.981); catalogued as COSV58010558; called by muse, mutect2
- CD1E | c.200G>A p.W67* | Nonsense Mutation (SNP) | VAF 150/577 reads (26%) | catalogued as COSV100936908; called by muse, mutect2, varscan2
- CD276 | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 128/644 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV59206020; called by muse, mutect2, varscan2
- CDC42BPG | c.3641C>T p.P1214L | Missense Mutation (SNP) | VAF 129/566 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs751025247; called by muse, mutect2, varscan2
- CDH8 | c.1013G>A p.R338K | Missense Mutation (SNP) | VAF 41/264 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV54895711; called by muse, mutect2, varscan2
- CDK18 | c.628G>A p.E210K (on ENST00000506784 / NM_212503.3; = p.E180K on NM_002596.4) | Missense Mutation (SNP) | VAF 67/416 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as rs761266287; called by muse, mutect2, varscan2
- CEACAM21 | c.847C>T p.P283S (on ENST00000401445 / NM_001098506.4; = p.P282S on NM_033543.6) | Missense Mutation (SNP) | VAF 20/469 reads (4%) | SIFT tolerated (0.79); PolyPhen benign (0.059); catalogued as rs1232057161, COSV99494629; called by muse, mutect2
- CENPJ | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV101121505; called by muse, mutect2
- CFAP54 | c.6404C>T p.S2135F | Missense Mutation (SNP) | VAF 67/287 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV61576159; called by muse, mutect2, varscan2
- CHD5 | c.5323G>A p.E1775K | Missense Mutation (SNP) | VAF 48/402 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99313452; called by muse, varscan2
- CHIA | c.481G>A p.E161K (on ENST00000343320; = p.E53K on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs866842630, COSV58476663; called by muse, mutect2, varscan2
- CMYA5 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 94/346 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV71408623; called by muse, mutect2, varscan2
- CNTN4 | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 62/370 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs755374986, COSV61880234; called by muse, mutect2, varscan2
- CNTNAP5 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 54/381 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70512242; called by muse, mutect2, varscan2
- COL11A1 | c.3587C>T p.P1196L | Missense Mutation (SNP) | VAF 48/312 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62184532; called by muse, mutect2, varscan2
- COL18A1 | c.2570T>C p.V857A (on ENST00000359759 / NM_130444.3; = p.V622A on NM_030582.4) | Missense Mutation (SNP) | VAF 56/333 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.242); catalogued as rs751825145; called by muse, mutect2, varscan2
- COL28A1 | c.2270G>A p.G757E | Missense Mutation (SNP) | VAF 141/405 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758952348, COSV68084664; called by muse, mutect2, varscan2
- COL4A4 | c.1909C>T p.P637S | Missense Mutation (SNP) | VAF 154/500 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.111); catalogued as rs775076627; called by muse, mutect2, varscan2
- COL4A5 | c.781-1G>A p.X261_splice | Splice Site (SNP) | VAF 38/510 reads (7%) | catalogued as CD961905; called by muse, mutect2
- COL4A6 | c.3430C>T p.P1144S | Missense Mutation (SNP) | VAF 118/484 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57878156; called by muse, mutect2, varscan2
- COL6A5 | c.7176G>A p.W2392* (on ENST00000312481; = p.W2388* on NM_153264.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 50/353 reads (14%) | catalogued as COSV55201261; called by muse, mutect2, varscan2
- COL7A1 | c.5533G>A p.G1845R | Missense Mutation (SNP) | VAF 59/475 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM104438; called by muse, mutect2, varscan2
- COL8A2 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 82/559 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57443500; called by muse, mutect2, varscan2
- COL9A1 | c.1379G>A p.G460E | Missense Mutation (SNP) | VAF 44/278 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100295912; called by muse, mutect2, varscan2
- CPLANE1 | c.9454C>T p.P3152S | Missense Mutation (SNP) | VAF 28/397 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV57061748; called by muse, mutect2
- CRB1 | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 50/550 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1163031172; called by muse, mutect2
- CSF2RB | c.2272C>T p.P758S | Missense Mutation (SNP) | VAF 233/722 reads (32%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.738); catalogued as COSV53261381; called by muse, mutect2, varscan2
- CSMD2 | c.6196C>T p.R2066W | Missense Mutation (SNP) | VAF 142/391 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs371966514; called by muse, mutect2, varscan2
- CSMD3 | c.8950G>A p.D2984N (on ENST00000297405 / NM_001363185.1; = p.D2815N on NM_052900.3) | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52123663; called by muse, mutect2, varscan2
- CT47A6 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 122/290 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.188); catalogued as rs754387926, COSV70031670; called by muse, mutect2, varscan2
- CXCR2 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 34/542 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.009); catalogued as rs2228413; called by muse, mutect2
- CYP4F8 | c.1398G>A p.R466= | Splice Region (SNP) | VAF 55/280 reads (20%) | catalogued as COSV100358127; called by muse, mutect2, varscan2
- DCHS2 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 134/507 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.019); catalogued as rs963522517, COSV59727814; called by muse, mutect2, varscan2
- DEFB119 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 28/488 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as rs867079819, COSV53620081; called by muse, mutect2
- DEFB119 | c.175T>A p.S59T | Missense Mutation (SNP) | VAF 28/492 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.202); catalogued as COSV53621361, COSV99489118; called by muse, mutect2
- DENND10 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 66/300 reads (22%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.973); catalogued as rs144364814, COSV63858284; called by muse, mutect2, varscan2
- DHRS4 | c.422A>T p.N141I | Missense Mutation (SNP) | VAF 76/317 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779623712; called by muse, mutect2, varscan2
- DNAH1 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 108/418 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV70227981; called by muse, mutect2, varscan2
- DNAH1 | c.9680C>T p.S3227F | Missense Mutation (SNP) | VAF 44/356 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1349184967; called by muse, mutect2, varscan2
- DNAH17 | c.8693G>A p.R2898Q | Missense Mutation (SNP) | VAF 91/412 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); catalogued as rs773351881; called by muse, mutect2, varscan2
- DNAH5 | c.6080C>T p.S2027F | Missense Mutation (SNP) | VAF 79/230 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99453131; called by muse, mutect2, varscan2
- DSG3 | c.2813C>T p.S938L | Missense Mutation (SNP) | VAF 68/408 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV99934643; called by muse, varscan2
- DSP | c.6361G>A p.G2121R | Missense Mutation (SNP) | VAF 118/389 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs368227724; called by muse, mutect2, varscan2
- DST | c.16191C>A p.F5397L (on ENST00000361203 / NM_001374722.1; = p.F2985L on NM_015548.5) | Missense Mutation (SNP) | VAF 64/441 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV55036042; called by muse, varscan2
- DUSP16 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 147/687 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs757949409, COSV53806019; called by muse, mutect2, varscan2
- EDN2 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 72/456 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV65423436; called by muse, mutect2, varscan2
- EFCAB8 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 79/312 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as rs1228427871; called by muse, mutect2, varscan2
- EID2 | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 47/798 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs1011075161; called by muse, mutect2
- ELOA2 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 114/539 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV55295940; called by muse, mutect2, varscan2
- ENPP7 | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 95/300 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as rs1555823807; called by muse, mutect2, varscan2
- EPHA1 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 118/670 reads (18%) | catalogued as rs141528182; called by muse, mutect2, varscan2
- EPM2A | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 47/491 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as rs754779408; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPPK1 | c.2762G>A p.G921D | Missense Mutation (SNP) | VAF 58/367 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs782505942; called by muse, mutect2, varscan2
- ERBB4 | c.2377C>T p.Q793* | Nonsense Mutation (SNP) | VAF 66/468 reads (14%) | catalogued as COSV61482964; called by muse, mutect2, varscan2
- ERC2 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 149/636 reads (23%) | catalogued as COSV55612411; called by muse, mutect2, varscan2
- ERRFI1 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 170/431 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs535836763, COSV66310998; called by muse, mutect2, varscan2
- ESR1 | c.1117C>T p.H373Y | Missense Mutation (SNP) | VAF 92/312 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.251); catalogued as COSV52798151; called by muse, mutect2, varscan2
- EXOC1 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 115/375 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV62120012; called by muse, mutect2, varscan2
- F8 | c.6190C>A p.Q2064K | Missense Mutation (SNP) | VAF 29/456 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as CM161997; called by muse, mutect2
- F8 | c.5632C>T p.H1878Y | Missense Mutation (SNP) | VAF 94/559 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.692); catalogued as CD1313696; called by muse, mutect2, varscan2
- FAAH2 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 110/406 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1254403222, COSV66506076, COSV66506223; called by muse, varscan2
- FAM47A | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 207/698 reads (30%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.731); catalogued as rs764031941, COSV60495676, COSV60499390; called by muse, mutect2, varscan2
- FAM47C | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 80/676 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.592); catalogued as COSV63726658, COSV63727648; called by muse, mutect2, varscan2
- FAM47C | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 26/794 reads (3%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.475); catalogued as COSV63723585; called by muse, mutect2
- FAR2 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 74/276 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.133); catalogued as rs1475516172; called by muse, mutect2, varscan2
- FAT4 | c.5362C>T p.R1788C | Missense Mutation (SNP) | VAF 135/492 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs768397789, COSV58686429; called by muse, mutect2, varscan2
- FBXO24 | c.1177G>A p.D393N (on ENST00000241071 / NM_033506.3; = p.D431N on NM_012172.5) | Missense Mutation (SNP) | VAF 170/504 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.848); catalogued as COSV99575541; called by muse, mutect2, varscan2
- FBXW12 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 71/288 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV56484084; called by muse, mutect2, varscan2
- FGA | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 159/527 reads (30%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV100120320, COSV99042800; called by muse, mutect2, varscan2
- FGD6 | c.2620C>T p.H874Y | Missense Mutation (SNP) | VAF 99/362 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV59697502; called by muse, mutect2, varscan2
- FLG | c.6557C>T p.S2186F | Missense Mutation (SNP) | VAF 42/720 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.165); catalogued as COSV100911407; called by muse, mutect2
- FLG2 | c.5078G>A p.G1693E | Missense Mutation (SNP) | VAF 161/576 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.033); catalogued as rs1475446263, COSV66174355; called by muse, mutect2, varscan2
- FLT1 | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); catalogued as rs553261958, COSV56716468; called by muse, mutect2, varscan2
- FLT4 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 96/310 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV56127288; called by muse, varscan2
- FMN2 | c.2968C>T p.P990S | Missense Mutation (SNP) | VAF 95/546 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.985); catalogued as rs1460714930; called by muse, mutect2, varscan2
- FMNL3 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 82/398 reads (21%) | catalogued as COSV53299136; called by muse, varscan2
- FRAS1 | c.10846C>T p.P3616S | Missense Mutation (SNP) | VAF 52/434 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV53606439; called by muse, mutect2, varscan2
- FSCB | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 69/306 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs952273069, COSV61218150, COSV61218485; called by muse, mutect2, varscan2
- FSD2 | c.1763G>A p.R588Q | Missense Mutation (SNP) | VAF 119/480 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.905); catalogued as rs757036146, COSV58009471; called by muse, mutect2, varscan2
- FSHB | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 71/370 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1159738542, COSV54222557; called by muse, mutect2, varscan2
- FYB1 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 94/280 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV60946571; called by muse, mutect2, varscan2
- GABRB2 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 82/245 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV50904309; called by muse, mutect2, varscan2
- GASK1B | c.1496G>A p.R499K | Missense Mutation (SNP) | VAF 106/401 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751022476; called by muse, mutect2, varscan2
- GBE1 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 68/276 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs775083576, COSV70096506; called by muse, mutect2, varscan2
- GGT2 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1363448595; called by muse, mutect2, varscan2
- GGT7 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 100/380 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV60539971; called by muse, mutect2, varscan2
- GH2 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 36/561 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV60427648; called by muse, mutect2
- GIMAP4 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 192/617 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as rs1021786738; called by muse, mutect2, varscan2
- GLYAT | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 103/356 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.269); catalogued as rs752514559, COSV53538436; called by muse, mutect2, varscan2
- GMNC | c.988G>A p.V330I | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1440795461; called by muse, mutect2, varscan2
- GOLGB1 | c.6872C>T p.S2291F | Missense Mutation (SNP) | VAF 17/480 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs1022926968, COSV61466065; called by muse, mutect2
- GPR141 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 252/613 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759565313, COSV57731278, COSV57732248; called by muse, mutect2, varscan2
- GPX6 | c.543G>A p.W181* | Nonsense Mutation (SNP) | VAF 31/485 reads (6%) | catalogued as COSV62657745; called by muse, mutect2
- GRAP2 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 118/571 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.213); catalogued as rs1019235957; called by muse, varscan2
- GRIK1 | c.2596G>A p.D866N | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV58711262, COSV58720990; called by muse, mutect2, varscan2
- GRIN2A | c.2557T>G p.C853G | Missense Mutation (SNP) | VAF 45/349 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV58019441; called by muse, mutect2, varscan2
- GRIN2B | c.2652G>A p.M884I | Missense Mutation (SNP) | VAF 54/482 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs761708533, COSV74207803; called by muse, mutect2, varscan2
- GRIN3A | c.3268C>T p.R1090C | Missense Mutation (SNP) | VAF 65/408 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs142270850, COSV62452752; called by muse, mutect2, varscan2
- GRM3 | c.659G>A p.G220D | Missense Mutation (SNP) | VAF 221/743 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1311013179; called by muse, mutect2, varscan2
- GTSE1 | c.496T>C p.Y166H | Missense Mutation (SNP) | VAF 159/679 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71889006; called by muse, mutect2, varscan2
- GYS2 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 86/337 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV53924583, COSV53929660; called by muse, mutect2, varscan2
- HAGH | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 77/330 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs563988047, COSV68400668; called by muse, mutect2, varscan2
- HCN1 | c.1517G>A p.G506E | Missense Mutation (SNP) | VAF 78/244 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57503052; called by muse, mutect2, varscan2
- HGF | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 24/606 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV55952328; called by muse, mutect2
- HIVEP1 | c.4715C>T p.S1572F | Missense Mutation (SNP) | VAF 66/448 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs1438659427, COSV65102457; called by muse, mutect2, varscan2
- HNF4G | c.175G>A p.D59N (on ENST00000354370 / NM_001330561.2; = p.D106N on NM_004133.5) | Missense Mutation (SNP) | VAF 48/245 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753631527; called by muse, mutect2, varscan2
- HNRNPC | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 42/388 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV100193121; called by muse, mutect2, varscan2
- HOXB1 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 142/615 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1247441581; called by muse, mutect2, varscan2
- HOXB3 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 189/679 reads (28%) | catalogued as COSV61144374; called by muse, mutect2, varscan2
- HTR3A | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 100/311 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs370765647; called by muse, mutect2, varscan2
- HTR4 | c.153G>A p.R51= | Splice Region (SNP) | VAF 28/159 reads (18%) | catalogued as rs1221737892; called by muse, mutect2, varscan2
- HUWE1 | c.12154G>A p.G4052R | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as rs781802874; called by muse, mutect2
- HYDIN | c.9769G>A p.G3257S | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV59274892, COSV99993339; called by muse, mutect2
- IFNE | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 120/326 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.846); catalogued as rs369605432; called by muse, mutect2, varscan2
- IFT52 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as rs867359866, COSV65974425, COSV65974514; called by muse, mutect2, varscan2
- IGLV5-45 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 51/435 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.47); catalogued as rs768484152; called by muse, mutect2, varscan2
- IGSF1 | c.2584G>A p.D862N | Missense Mutation (SNP) | VAF 43/310 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs772636261, COSV63839685; called by muse, mutect2, varscan2
- IL18R1 | c.1358G>A p.R453K | Missense Mutation (SNP) | VAF 76/331 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.284); catalogued as rs749539770; called by muse, mutect2, varscan2
- IL20RA | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 132/493 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.214); catalogued as rs868505002; called by muse, mutect2, varscan2
- IL37 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 30/442 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1384106006; called by muse, mutect2
- IL9R | c.579G>A p.E193= | Splice Region (SNP) | VAF 25/486 reads (5%) | catalogued as rs767109432; called by muse, mutect2
- INHBE | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 179/553 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV99875314; called by muse, mutect2, varscan2
- IRGM | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 137/433 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as rs930645632, COSV72988771; called by muse, mutect2, varscan2
- ITGB3 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 149/598 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV101457574; called by muse, mutect2
- ITSN1 | c.3730G>A p.E1244K | Missense Mutation (SNP) | VAF 100/326 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV67156977; called by muse, mutect2, varscan2
- IVL | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 176/683 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.036); catalogued as rs746372757, COSV64216793; called by muse, mutect2, varscan2
- JAG1 | c.2911T>C p.S971P | Missense Mutation (SNP) | VAF 83/230 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750570683; called by muse, mutect2, varscan2
- KAT2A | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 60/437 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.352); catalogued as rs1555667340; called by muse, mutect2, varscan2
- KCNA3 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 29/649 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1049290141; called by muse, mutect2
- KIF2C | c.1850C>T p.P617L | Missense Mutation (SNP) | VAF 54/308 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs201494235; called by muse, mutect2, varscan2
- KIF6 | c.145G>T p.V49L | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV54679561; called by muse, mutect2, varscan2
- KIRREL3 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs747435837; called by muse, mutect2
- KLHL30 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 44/352 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs763898027; called by muse, mutect2, varscan2
- KLHL5 | c.1162C>T p.L388F | Missense Mutation (SNP) | VAF 123/484 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV54673490; called by muse, mutect2, varscan2
- KLK14 | c.205G>C p.G69R | Missense Mutation (SNP) | VAF 101/404 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV50070389; called by muse, mutect2, varscan2
- KMT2C | c.5738G>A p.S1913N | Missense Mutation (SNP) | VAF 21/833 reads (3%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1563290947; called by muse, mutect2
- KMT2D | c.12991C>T p.P4331S | Missense Mutation (SNP) | VAF 76/863 reads (9%) | SIFT tolerated, low confidence (0.54); PolyPhen probably damaging (0.992); catalogued as COSV56461937; called by muse, mutect2
- LARP4 | c.1843C>T p.R615* | Nonsense Mutation (SNP) | VAF 72/310 reads (23%) | catalogued as COSV53324578; called by muse, mutect2, varscan2
- LDB2 | c.1049G>A p.S350N | Missense Mutation (SNP) | VAF 84/583 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.135); catalogued as rs1354990861; called by muse, mutect2, varscan2
- LHX8 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 29/408 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV53957111; called by muse, mutect2
- LILRB4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 108/438 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); catalogued as COSV54406647; called by muse, varscan2
- LMTK2 | c.3562C>T p.P1188S | Missense Mutation (SNP) | VAF 262/828 reads (32%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs1204969895; called by muse, mutect2, varscan2
- LMTK2 | c.3563C>T p.P1188L | Missense Mutation (SNP) | VAF 259/821 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as rs535375938; called by muse, mutect2, varscan2
- LMX1A | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 20/414 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs1239935443; called by muse, mutect2
- LRRC49 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 66/295 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs377618599; called by muse, mutect2, varscan2
- MAGEA10 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 97/533 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.145); catalogued as COSV54884313; called by muse, mutect2, varscan2
- MAGEB1 | c.663G>A p.W221* | Nonsense Mutation (SNP) | VAF 203/693 reads (29%) | catalogued as rs777909623, COSV66775681; called by muse, mutect2, varscan2
- MAGEL2 | c.1120G>A p.G374R | Missense Mutation (SNP) | VAF 110/599 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100046377; called by muse, mutect2, varscan2
- MAP3K15 | c.3055C>T p.L1019F | Missense Mutation (SNP) | VAF 71/522 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs761795801, COSV58827458; called by muse, mutect2, varscan2
- MAP3K4 | c.4267G>A p.D1423N | Missense Mutation (SNP) | VAF 106/405 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.923); catalogued as COSV62329937; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 170/742 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.551); catalogued as rs1231073035; called by muse, mutect2, varscan2
- MAPK8IP3 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 30/387 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV51723581; called by muse, mutect2
- MAPT | c.2174G>A p.G725E (on ENST00000262410 / NM_001377265.1; = p.G333E on NM_005910.5) | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52239832; called by muse, mutect2
- MCTP2 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 105/563 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59141506; called by muse, mutect2, varscan2
- MDN1 | c.4546C>T p.R1516C | Missense Mutation (SNP) | VAF 101/375 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs1234920779, COSV65519350, COSV65521119; called by muse, mutect2, varscan2
- MDN1 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 123/430 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs747123372, COSV101020896; called by muse, mutect2, varscan2
- ME1 | c.212G>A p.R71K | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs758002631; called by muse, mutect2, varscan2
- MEN1 | c.1532C>T p.T511I | Missense Mutation (SNP) | VAF 142/595 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1347992299; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MEP1A | c.1889C>T p.S630L | Missense Mutation (SNP) | VAF 163/536 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs746944566, COSV57921438; called by muse, mutect2, varscan2
- MGA | c.5570C>T p.S1857L (on ENST00000219905 / NM_001164273.1; = p.S1648L on NM_001080541.2) | Missense Mutation (SNP) | VAF 112/512 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as rs764277967, COSV54951198; called by muse, mutect2, varscan2
- MGAM | c.4469C>T p.T1490I | Missense Mutation (SNP) | VAF 70/511 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); catalogued as COSV72073853; called by muse, mutect2, varscan2
- MINK1 | c.2333C>T p.S778F | Missense Mutation (SNP) | VAF 177/482 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs766833785; called by muse, mutect2, varscan2
- MKLN1 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 72/914 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as rs770487392; called by muse, mutect2
- MMRN1 | c.3272C>T p.S1091F | Missense Mutation (SNP) | VAF 55/279 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53343322; called by muse, mutect2, varscan2
- MNDA | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 123/484 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.04); catalogued as rs1288507859, COSV63742406; called by muse, mutect2, varscan2
- MORC1 | c.2698G>A p.E900K | Missense Mutation (SNP) | VAF 74/362 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as rs866650943, COSV51721626; called by muse, mutect2, varscan2
- MPC1L | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 21/612 reads (3%) | SIFT tolerated (0.38); catalogued as COSV70660147; called by muse, mutect2
- MPP6 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 122/301 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99757408; called by muse, mutect2, varscan2
- MPV17L | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 112/421 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1289076086; called by muse, mutect2, varscan2
- MRAP2 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 39/293 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57632375; called by muse, mutect2, varscan2
- MROH5 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV71302600; called by muse, varscan2
- MRPS36 | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 42/438 reads (10%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as rs148995834; called by muse, mutect2
- MS4A8 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 71/427 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.922); catalogued as COSV55754212; called by muse, mutect2, varscan2
- MSR1 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 49/300 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); catalogued as rs141804459; called by muse, mutect2, varscan2
- MUC16 | c.27748G>A p.A9250T | Missense Mutation (SNP) | VAF 104/439 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs376062753; called by muse, mutect2, varscan2
- MUC16 | c.6527G>A p.G2176E | Missense Mutation (SNP) | VAF 119/451 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as rs778489702; called by muse, mutect2, varscan2
- MUC17 | c.11533C>T p.P3845S | Missense Mutation (SNP) | VAF 75/640 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV60296796; called by muse, mutect2, varscan2
- MXRA5 | c.5108G>A p.G1703E | Missense Mutation (SNP) | VAF 79/693 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV54225163; called by muse, mutect2, varscan2
- MYH3 | c.3358G>A p.E1120K | Missense Mutation (SNP) | VAF 82/324 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV56869973; called by muse, mutect2, varscan2
- MYH8 | c.5581C>T p.R1861C | Missense Mutation (SNP) | VAF 97/309 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs760517620; called by muse, mutect2, varscan2
- MYL9 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 62/466 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV54072191, COSV54073196; called by muse, mutect2, varscan2
- MYLK | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 73/302 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.194); catalogued as rs778852995, COSV60618074; called by muse, mutect2, varscan2
- MYO10 | c.4459C>T p.R1487W | Missense Mutation (SNP) | VAF 110/366 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368697553, COSV57028015; called by muse, mutect2, varscan2
- MYO15A | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 156/546 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs771720592; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO18B | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 220/442 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); catalogued as rs767592994; called by mutect2, varscan2
- NAALADL2 | c.1759C>T p.P587S | Missense Mutation (SNP) | VAF 58/323 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71983506, COSV71986945; called by muse, mutect2, varscan2
- NAPEPLD | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 169/1023 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs746125875, COSV58522804; called by muse, mutect2, varscan2
- NDUFC2 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 206/525 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs371664886; called by muse, mutect2, varscan2
- NEB | c.6265C>T p.H2089Y | Missense Mutation (SNP) | VAF 50/375 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV99427392; called by muse, mutect2, varscan2
- NEUROD4 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 158/565 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.36); catalogued as rs1241017522, COSV54472486, COSV54473978; called by muse, mutect2, varscan2
- NF1 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 59/367 reads (16%) | catalogued as CM961025, COSV62197350; called by muse, mutect2, varscan2
- NIPSNAP1 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 132/466 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs748363591; called by muse, mutect2, varscan2
- NLRP10 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 178/639 reads (28%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.808); catalogued as COSV60778612; called by muse, mutect2, varscan2
- NLRP12 | c.2903C>T p.P968L | Missense Mutation (SNP) | VAF 73/348 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs771953294; called by muse, mutect2, varscan2
- NLRP4 | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 88/296 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.577); catalogued as COSV100016027, COSV56707914; called by muse, mutect2
- NLRP5 | c.2708G>A p.G903E | Missense Mutation (SNP) | VAF 32/550 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as COSV66766268; called by muse, mutect2
- NLRP7 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 221/853 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1355632267, COSV60172417; called by muse, mutect2, varscan2
- NODAL | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 173/604 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.425); catalogued as rs1564667208; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOL9 | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 36/349 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV66626198; called by muse, mutect2, varscan2
- NOS1 | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as COSV57617334; called by muse, mutect2
- NPLOC4 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 112/465 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58616722; called by muse, mutect2, varscan2
- NPY2R | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 106/464 reads (23%) | catalogued as COSV61529560; called by muse, mutect2, varscan2
- NTN1 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 25/414 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1190617393; called by muse, mutect2
- OBSCN | c.7529C>T p.P2510L | Missense Mutation (SNP) | VAF 133/634 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.516); catalogued as rs1553454365; called by muse, varscan2
- OBSCN | c.13375G>A p.V4459M | Missense Mutation (SNP) | VAF 142/550 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs1266647266; called by muse, mutect2, varscan2
- OOEP | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 80/553 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs766011148; called by muse, mutect2
- OR10G2 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 93/335 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.704); catalogued as rs199836300, COSV73390376; called by muse, mutect2, varscan2
- OR10H3 | c.152G>A p.W51* | Nonsense Mutation (SNP) | VAF 159/553 reads (29%) | catalogued as rs1289708114; called by muse, mutect2, varscan2
- OR10J3 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 197/640 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV59954473; called by muse, mutect2, varscan2
- OR10W1 | c.861G>T p.E287D | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.062); catalogued as COSV67720342; called by muse, mutect2
- OR4A16 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 59/488 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.167); catalogued as rs1389734335, COSV59041785; called by muse, mutect2, varscan2
- OR4C15 | c.523C>T p.R175C (on ENST00000314644; = p.R121C on NM_001001920.2) | Missense Mutation (SNP) | VAF 153/425 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); catalogued as rs267602969, COSV58951118, COSV58951281; called by muse, mutect2, varscan2
- OR4K17 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 59/439 reads (13%) | catalogued as rs140042697, COSV59649222; called by muse, mutect2, varscan2
- OR4X2 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 34/440 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100183376, COSV56582108; called by muse, mutect2
- OR51A7 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 134/384 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63788783; called by muse, mutect2, varscan2
- OR51B4 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 115/344 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as rs769382012, COSV66517158, COSV66517252; called by muse, mutect2, varscan2
- OR51F2 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 44/334 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV59065125, COSV59066263; called by muse, mutect2, varscan2
- OR51G1 | c.652C>T p.L218F | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.191); catalogued as COSV58970671; called by muse, mutect2, varscan2
- OR5AS1 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs186626466; called by muse, mutect2, varscan2
- OR5H14 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 132/606 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs768046296, COSV71193536; called by muse, varscan2
- OR6N2 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 136/486 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as rs763529373; called by muse, mutect2, varscan2
- OR6T1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 138/409 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770876608, COSV58305477; called by muse, mutect2, varscan2
- OR8U1 | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 228/665 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV56414498; called by muse, varscan2
- OR9Q2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 176/590 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs779193944; called by muse, mutect2, varscan2
- OSBPL7 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 26/508 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99137095; called by muse, mutect2
- OTOL1 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as rs770064419; called by muse, mutect2, varscan2
- PABPC1 | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs746403429, COSV59400730; called by mutect2, varscan2
- PAK5 | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 84/315 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62028339; called by muse, mutect2, varscan2
- PAPPA | c.3053G>A p.G1018E | Missense Mutation (SNP) | VAF 116/381 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV60283546; called by muse, mutect2, varscan2
- PATJ | c.2968C>T p.P990S | Missense Mutation (SNP) | VAF 22/295 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.038); catalogued as rs764523491, COSV57160953; called by muse, mutect2
- PCARE | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 34/604 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1246334485; called by muse, mutect2
- PCDH1 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 142/391 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54618305; called by muse, mutect2, varscan2
- PCDH18 | c.2977G>A p.D993N | Missense Mutation (SNP) | VAF 148/555 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs754884852, COSV61269913; called by muse, mutect2, varscan2
- PCDHA5 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 183/554 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782629988, COSV65349225; called by muse, mutect2, varscan2
- PCDHB1 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 140/391 reads (36%) | catalogued as rs868950000, COSV60631593; called by muse, mutect2, varscan2
- PCED1A | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 22/254 reads (9%) | catalogued as rs1555794910; called by muse, mutect2
- PCED1B | c.407G>A p.W136* | Nonsense Mutation (SNP) | VAF 146/638 reads (23%) | catalogued as rs1454443460; called by muse, mutect2, varscan2
- PCK1 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 62/490 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.065); catalogued as rs1257814791; called by muse, mutect2, varscan2
- PCLO | c.15226C>T p.R5076* | Nonsense Mutation (SNP) | VAF 86/538 reads (16%) | catalogued as COSV61623463; called by muse, mutect2, varscan2
- PCLO | c.15133C>T p.H5045Y | Missense Mutation (SNP) | VAF 107/257 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747790550; called by muse, mutect2, varscan2
- PCLO | c.7852C>T p.P2618S | Missense Mutation (SNP) | VAF 140/676 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs759415107; called by muse, mutect2, varscan2
- PCLO | c.6673G>A p.E2225K | Missense Mutation (SNP) | VAF 112/561 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV61665165; called by muse, mutect2, varscan2
- PCNX2 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 130/406 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); catalogued as rs781497332, COSV99266538; called by muse, mutect2, varscan2
- PF4 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 114/415 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99933126; called by muse, mutect2, varscan2
- PGK2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 72/506 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as COSV59165700, COSV59165854; called by muse, varscan2
- PGK2 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 79/534 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV59162863; called by muse, varscan2
- PGLYRP4 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 73/266 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1203523348; called by muse, mutect2, varscan2
- PGLYRP4 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 143/574 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV100668370; called by muse, mutect2, varscan2
- PHKA2 | c.2690A>T p.Y897F | Missense Mutation (SNP) | VAF 120/462 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.766); catalogued as rs1409603276; called by muse, mutect2, varscan2
- PI4KA | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 75/591 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs1195643948, COSV55425306; called by muse, mutect2, varscan2
- PIK3CA | c.3103G>A p.A1035T | Missense Mutation (SNP) | VAF 30/377 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55892080; called by muse, mutect2
- PKD2 | c.2334G>A p.M778I | Missense Mutation (SNP) | VAF 60/293 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV52937467; called by muse, mutect2, varscan2
- PKP1 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 80/629 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751008697, COSV99825252; called by muse, mutect2, varscan2
- PLCB4 | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 85/271 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV53819678; called by muse, mutect2, varscan2
- PLCE1 | c.1531C>T p.L511F | Missense Mutation (SNP) | VAF 61/467 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.572); catalogued as rs772621903; called by muse, mutect2, varscan2
- PLOD3 | c.2033C>T p.A678V | Missense Mutation (SNP) | VAF 82/587 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs781689698; called by muse, mutect2, varscan2
- PLPPR3 | c.1309G>A p.E437K (on ENST00000520876 / NM_001270366.2; = p.E465K on NM_024888.2) | Missense Mutation (SNP) | VAF 115/603 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs1211239225; called by muse, mutect2, varscan2
- PLXNB3 | c.3028C>T p.R1010C | Missense Mutation (SNP) | VAF 106/606 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as rs781907647, COSV62796565; called by muse, mutect2, varscan2
- PNLDC1 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 48/398 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs754073075; called by muse, mutect2, varscan2
- PODN | c.973G>A p.E325K (on ENST00000395871; = p.E277K on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/367 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.157); catalogued as rs775826618, COSV57012702; called by muse, mutect2, varscan2
- POLD1 | c.2675C>T p.S892F | Missense Mutation (SNP) | VAF 104/438 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV99570106; called by muse, mutect2, varscan2
- POLR3E | c.1384C>T p.Q462* | Nonsense Mutation (SNP) | VAF 101/368 reads (27%) | catalogued as COSV100241989; called by muse, mutect2, varscan2
- POM121C | c.1097C>T p.S366F (on ENST00000607367; = p.S124F on NM_001099415.3) | Missense Mutation (SNP) | VAF 133/596 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs373128587; called by muse, mutect2, varscan2
- PPARG | c.145G>A p.D49N (on ENST00000287820 / NM_015869.5; = p.D19N on NM_005037.7) | Missense Mutation (SNP) | VAF 94/461 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as rs777067241; called by muse, mutect2, varscan2
- PPFIA2 | c.3604C>T p.P1202S | Missense Mutation (SNP) | VAF 133/509 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61027363; called by muse, mutect2, varscan2
- PPP1R3A | c.1994C>T p.S665L | Missense Mutation (SNP) | VAF 113/698 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52882141; called by muse, mutect2, varscan2
- PPP1R9B | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 142/508 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as rs1210750776; called by muse, mutect2, varscan2
- PPP4R4 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 73/548 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as rs1566674776; called by muse, mutect2, varscan2
- PPP6C | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 116/377 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV65207801; called by muse, mutect2, varscan2
- PREX2 | c.4444C>T p.L1482F | Missense Mutation (SNP) | VAF 49/305 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761771548; called by muse, mutect2, varscan2
- PRICKLE2 | c.430C>T p.R144* (on ENST00000295902; = p.R88* on NM_198859.4) | Nonsense Mutation (SNP) | VAF 76/291 reads (26%) | catalogued as rs1365717280; called by muse, mutect2, varscan2
- PRIMA1 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 124/449 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.469); catalogued as COSV60263739; called by muse, mutect2, varscan2
- PRKN | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 49/326 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs761430731, COSV58215260; called by muse, mutect2, varscan2
- PRSS35 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 146/477 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs137859515; called by muse, varscan2
- PRUNE2 | c.1357G>A p.G453R | Missense Mutation (SNP) | VAF 52/438 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100945243, COSV65037676, COSV65040370; called by muse, mutect2, varscan2
- PSD3 | c.136C>T p.H46Y | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV58968896; called by muse, varscan2
- PSD4 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 36/559 reads (6%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs1470980219; called by muse, mutect2
- PSG1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 113/442 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as rs1058956; called by mutect2, varscan2
- PSG11 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 79/333 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV60455140; called by muse, mutect2, varscan2
- PSG6 | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 137/614 reads (22%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.781); catalogued as COSV51837029; called by muse, mutect2, varscan2
- PTCHD3 | c.1625G>A p.G542D | Missense Mutation (SNP) | VAF 138/452 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV71257304; called by muse, varscan2
- PTPRC | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 164/552 reads (30%) | SIFT tolerated (0.79); PolyPhen benign (0.037); catalogued as COSV61412107, COSV61422978; called by muse, mutect2, varscan2
- PTPRN2 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 159/931 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV67030896; called by muse, mutect2
- PTPRQ | c.4009G>A p.G1337R (on ENST00000616559; = p.G1295R on NM_001145026.2) | Missense Mutation (SNP) | VAF 46/385 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs776967574; called by muse, mutect2, varscan2
- PTPRR | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 114/462 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.395); catalogued as rs1162339248, COSV51725812; called by muse, mutect2, varscan2
- PTPRZ1 | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 239/762 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.103); catalogued as COSV66446890; called by muse, mutect2, varscan2
- PXDNL | c.3263C>T p.P1088L | Missense Mutation (SNP) | VAF 44/402 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750386407, COSV62480071; called by muse, mutect2, varscan2
- RAB3IP | c.751G>A p.E251K (on ENST00000550536 / NM_175623.4; = p.E235K on NM_022456.5) | Missense Mutation (SNP) | VAF 69/299 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56083281, COSV99923722; called by muse, mutect2, varscan2
- RABGAP1L | c.1579C>T p.R527* | Nonsense Mutation (SNP) | VAF 42/417 reads (10%) | catalogued as rs1462676250, COSV52278954; called by muse, varscan2
- RAD51B | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 115/403 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs769705231, COSV66843502; called by muse, mutect2, varscan2
- RBM38 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 128/523 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV61134224; called by muse, mutect2, varscan2
- RELN | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 110/657 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.073); catalogued as rs267601217, COSV58985849, COSV59014511; called by muse, mutect2, varscan2
- RFX6 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 102/357 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs967660677; called by muse, mutect2, varscan2
- RGPD3 | c.5200C>T p.P1734S | Missense Mutation (SNP) | VAF 28/625 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs1199802731, COSV58738567; called by muse, mutect2
- ROR2 | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 90/309 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs771882038; called by muse, mutect2, varscan2
- RPS6KA3 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 39/320 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV65388906; called by muse, mutect2, varscan2
- RYR1 | c.13526G>A p.G4509E | Missense Mutation (SNP) | VAF 14/436 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.103); catalogued as COSV62101850; called by muse, mutect2
- RYR2 | c.4972C>T p.L1658F | Missense Mutation (SNP) | VAF 169/611 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767540663, COSV100772602; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.7486C>T p.L2496F | Missense Mutation (SNP) | VAF 114/399 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV63698908; called by muse, mutect2, varscan2
- RYR2 | c.11464G>A p.E3822K | Missense Mutation (SNP) | VAF 98/378 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100773413; called by muse, mutect2, varscan2
- SAMD4A | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 79/625 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs756438692; called by muse, mutect2, varscan2
- SCG2 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 76/426 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs569665778, COSV59539775; called by muse, mutect2, varscan2
- SCN11A | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 83/346 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56576444; called by muse, mutect2, varscan2
- SCN5A | c.3947G>A p.R1316Q (on ENST00000333535 / NM_198056.3; = p.R1315Q on NM_000335.5) | Missense Mutation (SNP) | VAF 85/332 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs765907469, CM143810, COSV100346967, COSV61139531; called by muse, mutect2, varscan2
- SCN5A | c.1507C>T p.P503S | Missense Mutation (SNP) | VAF 27/422 reads (6%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.893); catalogued as rs1452180263; called by muse, mutect2
- SDC1 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 168/550 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs373072444, COSV54339897; called by muse, mutect2, varscan2
- SEC23B | c.1294G>A p.G432R | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs752607383; called by muse, mutect2
- SERINC5 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 117/333 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101549069; called by muse, mutect2, varscan2
- SERPINB13 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 49/232 reads (21%) | catalogued as COSV99500916; called by muse, mutect2, varscan2
- SETBP1 | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 171/578 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); catalogued as rs1055551345; called by muse, mutect2, varscan2
- SH2B1 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 126/494 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1406011506; called by muse, mutect2, varscan2
- SIGLEC6 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 45/459 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV58435044; called by muse, mutect2
- SIPA1L3 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 42/736 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs368942102; called by muse, mutect2
- SIRPG | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 27/379 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0.021); catalogued as COSV99403489; called by muse, mutect2
- SLC22A16 | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 77/524 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1196245215, COSV100397416; called by muse, mutect2, varscan2
- SLC22A25 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 117/355 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); catalogued as rs766375939, COSV60595436; called by muse, mutect2, varscan2
- SLC24A3 | c.1323C>T p.P441= | Splice Region (SNP) | VAF 32/394 reads (8%) | catalogued as COSV60116213, COSV60128380; called by muse, mutect2
- SLC34A1 | c.1627G>A p.G543S | Missense Mutation (SNP) | VAF 125/431 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as COSV53692052; called by muse, mutect2, varscan2
- SLC34A1 | c.1628G>A p.G543D | Missense Mutation (SNP) | VAF 126/430 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs766429764; called by muse, mutect2, varscan2
- SLC44A5 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 101/347 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV63770153; called by muse, mutect2, varscan2
- SLC5A8 | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 80/368 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV73310331, COSV73310495; called by muse, mutect2, varscan2
- SLC9A4 | c.2009G>A p.G670E | Missense Mutation (SNP) | VAF 95/321 reads (30%) | SIFT tolerated (0.88); PolyPhen benign (0.034); catalogued as COSV54830252; called by muse, mutect2, varscan2
- SMAD1 | c.1099C>T p.H367Y | Missense Mutation (SNP) | VAF 41/568 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs769874336; called by muse, mutect2
- SMOC2 | c.1111G>A p.E371K (on ENST00000356284 / NM_001166412.2; = p.E382K on NM_022138.3) | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62443754; called by muse, mutect2
- SORCS1 | c.1563C>T p.P521= | Splice Region (SNP) | VAF 55/245 reads (22%) | catalogued as rs1345226938; called by muse, mutect2, varscan2
- SPATA18 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 83/419 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.08); catalogued as COSV54641362; called by muse, mutect2, varscan2
- SPEN | c.9359C>T p.P3120L | Missense Mutation (SNP) | VAF 53/480 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749920639, COSV101005138; called by muse, mutect2, varscan2
- SPIRE2 | c.1417C>T p.R473* | Nonsense Mutation (SNP) | VAF 46/482 reads (10%) | catalogued as rs150516247; called by muse, mutect2
- SPO11 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 74/346 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs754164090; called by muse, mutect2, varscan2
- SPTA1 | c.6551C>T p.S2184L | Missense Mutation (SNP) | VAF 111/340 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as rs1396197746; called by muse, mutect2, varscan2
- SRC | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 27/876 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1346524802; called by muse, mutect2
- SRSF7 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 99/348 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs533792233, COSV57448363; called by muse, mutect2, varscan2
- STAB2 | c.6964C>T p.P2322S | Missense Mutation (SNP) | VAF 64/274 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs765335267, COSV66339636; called by muse, varscan2
- STK39 | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 40/367 reads (11%) | catalogued as COSV63594610; called by muse, mutect2, varscan2
- STON1 | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 68/374 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59137481; called by muse, mutect2, varscan2
- STPG2 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.283); catalogued as COSV54783241, COSV54825855; called by muse, mutect2
- STXBP2 | c.1158G>A p.M386I | Missense Mutation (SNP) | VAF 105/453 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV55404808; called by muse, mutect2, varscan2
- SVEP1 | c.7549G>A p.G2517R | Missense Mutation (SNP) | VAF 43/500 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as rs1270346796, COSV52838300; called by muse, mutect2
- SYF2 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 39/326 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs201199963; called by muse, mutect2, varscan2
- SYNE1 | c.3286G>A p.D1096N (on ENST00000367255 / NM_182961.4; = p.D1103N on NM_033071.3) | Missense Mutation (SNP) | VAF 170/548 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99571141; called by muse, mutect2, varscan2
- SYNJ2 | c.1918C>T p.P640S | Missense Mutation (SNP) | VAF 48/325 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1249759209; called by muse, mutect2, varscan2
- SYTL3 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 41/564 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs541039427; called by muse, mutect2
- TAF1L | c.2218G>T p.E740* | Nonsense Mutation (SNP) | VAF 172/552 reads (31%) | catalogued as COSV54260565; called by muse, mutect2, varscan2
- TAF1L | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 28/536 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV54260687; called by muse, mutect2
- TAF3 | c.2564A>T p.Y855F | Missense Mutation (SNP) | VAF 105/343 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV60206867; called by muse, mutect2, varscan2
- TAFA1 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 96/365 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV72040638; called by muse, mutect2, varscan2
- TBC1D5 | c.1913C>T p.S638F | Missense Mutation (SNP) | VAF 69/327 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53752396; called by muse, mutect2, varscan2
- TC2N | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 114/501 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.946); catalogued as rs994860688, COSV61748403; called by muse, mutect2, varscan2
- TCHH | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 106/370 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs755017096, COSV64273272; called by muse, mutect2, varscan2
- TDRKH | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 34/650 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.037); catalogued as COSV100162632; called by muse, mutect2
- TECRL | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 80/246 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV67089374; called by muse, mutect2, varscan2
- TECRL | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 70/354 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.877); catalogued as COSV101169369; called by muse, mutect2, varscan2
- TENM4 | c.5596G>A p.D1866N | Missense Mutation (SNP) | VAF 310/738 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as rs781457620; called by muse, mutect2, varscan2
- TFCP2L1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 81/485 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.523); catalogued as rs372808199; called by muse, mutect2, varscan2
- TGM1 | c.2147C>T p.P716L | Missense Mutation (SNP) | VAF 30/472 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767855778, COSV52863291; called by muse, mutect2
- THEMIS | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 173/597 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV64072471; called by muse, mutect2, varscan2
- THEMIS | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 73/612 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239522905; called by muse, mutect2, varscan2
- THSD1 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 142/447 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.666); catalogued as rs1188780320, COSV51631665; called by muse, mutect2, varscan2
- THSD7B | c.2290C>T p.R764* | Nonsense Mutation (SNP) | VAF 81/304 reads (27%) | catalogued as COSV55743911; called by muse, varscan2
- TKTL2 | c.1423C>T p.R475* | Nonsense Mutation (SNP) | VAF 87/375 reads (23%) | catalogued as rs200182075; called by muse, mutect2, varscan2
- TLL2 | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 104/324 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as rs149466962, COSV63574822; called by muse, mutect2, varscan2
- TLR4 | c.1779G>A p.W593* (on ENST00000355622 / NM_138554.5; = p.W553* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 44/497 reads (9%) | catalogued as rs5030720; called by muse, mutect2
- TLR5 | c.1844C>T p.S615L | Missense Mutation (SNP) | VAF 108/590 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV60557771; called by muse, mutect2, varscan2
- TMEM120B | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 90/395 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs560432972, COSV61183887; called by muse, mutect2, varscan2
- TMEM132C | c.1646C>T p.T549I | Missense Mutation (SNP) | VAF 74/265 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as rs1429056004; called by muse, mutect2, varscan2
- TMEM151B | c.1411G>A p.G471S | Missense Mutation (SNP) | VAF 18/424 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs990871178; called by muse, mutect2
- TMEM238L | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 41/250 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1187238735; called by muse, mutect2, varscan2
- TMEM94 | c.2678C>T p.P893L | Missense Mutation (SNP) | VAF 26/630 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV58595885; called by muse, mutect2
- TMPRSS11A | c.57G>A p.M19I | Missense Mutation (SNP) | VAF 122/400 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV58358548; called by muse, varscan2
- TMPRSS11B | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 83/354 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); catalogued as rs1028494914; called by muse, mutect2, varscan2
- TMPRSS12 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 86/438 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs753582397; called by muse, mutect2, varscan2
- TNFSF12-TNFSF13 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 65/442 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1211322156; called by muse, mutect2, varscan2
- TNR | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 140/543 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV54871971; called by muse, mutect2, varscan2
- TRANK1 | c.7065G>A p.M2355I | Missense Mutation (SNP) | VAF 168/652 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1244753873; called by muse, mutect2, varscan2
- TRIM49B | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 58/438 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs533366193; called by muse, mutect2, varscan2
- TRIM55 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 47/312 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs777178338; called by muse, mutect2, varscan2
- TRIO | c.8381C>T p.S2794F | Missense Mutation (SNP) | VAF 96/305 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.183); catalogued as COSV59989981; called by muse, mutect2, varscan2
- TRPM1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 62/269 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.14); catalogued as COSV56633065; called by muse, mutect2, varscan2
- TRPV4 | c.2584C>T p.R862C | Missense Mutation (SNP) | VAF 117/508 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.109); catalogued as rs149267166; called by muse, mutect2, varscan2
- TRRAP | c.3043C>T p.R1015W | Missense Mutation (SNP) | VAF 102/762 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781942215, COSV62849677; called by muse, mutect2, varscan2
- TSPAN17 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 104/334 reads (31%) | catalogued as rs536743163, COSV53779578; called by muse, mutect2, varscan2
- TTN | c.49573C>T p.L16525F (on ENST00000591111; = p.L9101F on NM_003319.4) | Missense Mutation (SNP) | VAF 60/456 reads (13%) | PolyPhen possibly damaging (0.654); catalogued as rs878953621; called by muse, mutect2, varscan2
- TTN | c.44893C>T p.P14965S (on ENST00000591111; = p.P7541S on NM_003319.4) | Missense Mutation (SNP) | VAF 73/501 reads (15%) | PolyPhen benign (0.187); catalogued as rs540303634; called by muse, mutect2, varscan2
- TTN | c.39445G>A p.E13149K (on ENST00000591111; = p.E5725K on NM_003319.4) | Missense Mutation (SNP) | VAF 36/304 reads (12%) | PolyPhen probably damaging (0.994); catalogued as rs762712953, COSV59960130; called by muse, mutect2, varscan2
- TTN | c.38023G>A p.A12675T (on ENST00000591111; = p.A5251T on NM_003319.4) | Missense Mutation (SNP) | VAF 80/269 reads (30%) | PolyPhen benign (0.356); catalogued as rs763386894; called by muse, mutect2, varscan2
- TTN | c.23113G>A p.G7705R (on ENST00000591111; = p.G6778R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/567 reads (13%) | PolyPhen probably damaging (1); catalogued as COSV60004511; called by muse, mutect2, varscan2
- UBR4 | c.7400C>T p.P2467L | Missense Mutation (SNP) | VAF 129/405 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100921071; called by muse, mutect2, varscan2
- UGT2B11 | c.1171G>A p.V391M | Missense Mutation (SNP) | VAF 55/690 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV101485253; called by muse, mutect2
- UHRF1BP1L | c.4253C>T p.S1418F | Missense Mutation (SNP) | VAF 98/386 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV54440958; called by muse, mutect2, varscan2
- UNC13C | c.4028G>A p.R1343Q | Missense Mutation (SNP) | VAF 83/355 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs770064369, COSV52839796, COSV52845310; called by muse, mutect2, varscan2
- UNC45B | c.2578G>A p.D860N | Missense Mutation (SNP) | VAF 119/399 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as rs753397675, COSV52098268; called by muse, mutect2, varscan2
- UNC80 | c.8404C>T p.L2802F | Missense Mutation (SNP) | VAF 40/317 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1227642683; called by muse, mutect2, varscan2
- URB2 | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 49/274 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV51037451; called by muse, mutect2, varscan2
- USF3 | c.6391C>T p.P2131S | Missense Mutation (SNP) | VAF 107/409 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57078242; called by muse, mutect2, varscan2
- VARS1 | c.2290C>T p.R764W | Missense Mutation (SNP) | VAF 154/525 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs55786236, COSV63305174; called by muse, mutect2, varscan2
- VIT | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 49/289 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64898920; called by muse, mutect2, varscan2
- VPS13B | c.9721G>A p.G3241R | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758775003; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VWDE | c.1898C>T p.P633L | Missense Mutation (SNP) | VAF 228/549 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs868504200; called by muse, mutect2, varscan2
- VWF | c.3360G>A p.W1120* | Nonsense Mutation (SNP) | VAF 122/427 reads (29%) | catalogued as CM1211910; called by muse, mutect2, varscan2
- WDR87 | c.4371G>A p.W1457* | Nonsense Mutation (SNP) | VAF 115/460 reads (25%) | catalogued as rs1400069056; called by muse, mutect2, varscan2
- XDH | c.2350C>T p.P784S | Missense Mutation (SNP) | VAF 73/368 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); catalogued as rs141938849; called by muse, mutect2, varscan2
- YBX2 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 234/630 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99142662; called by muse, mutect2, varscan2
- ZCCHC14 | c.401C>T p.S134F (on ENST00000268616; = p.S271F on NM_015144.3) | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.823); catalogued as COSV51886452; called by muse, mutect2, varscan2
- ZDHHC23 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 71/358 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs765689371; called by muse, mutect2, varscan2
- ZFP42 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 38/342 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as rs1309230542, COSV58816656, COSV58817195; called by muse, mutect2, varscan2
- ZFYVE16 | c.2504C>T p.P835L | Missense Mutation (SNP) | VAF 30/417 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100566128; called by muse, mutect2
- ZIM2 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 55/386 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.087); catalogued as COSV55641314; called by muse, mutect2, varscan2
- ZNF229 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 71/504 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs769889297; called by muse, mutect2, varscan2
- ZNF274 | c.1333C>T p.P445S (on ENST00000610905; = p.P340S on NM_016324.3) | Missense Mutation (SNP) | VAF 129/554 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV58762941; called by muse, mutect2, varscan2
- ZNF281 | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 152/611 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54166409, COSV54170132; called by muse, mutect2, varscan2
- ZNF334 | c.2030C>T p.S677F | Missense Mutation (SNP) | VAF 54/271 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV61619521; called by muse, mutect2, varscan2
- ZNF441 | c.797A>G p.Y266C | Missense Mutation (SNP) | VAF 81/411 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1028319956; called by muse, mutect2, varscan2
- ZNF449 | c.1448G>A p.R483K | Missense Mutation (SNP) | VAF 97/582 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV59346145; called by muse, mutect2, varscan2
- ZNF469 | c.8957G>A p.G2986E (on ENST00000437464; = p.G3014E on NM_001367624.2) | Missense Mutation (SNP) | VAF 96/468 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.169); catalogued as COSV71258329; called by muse, mutect2, varscan2
- ZNF479 | c.1039C>T p.H347Y | Missense Mutation (SNP) | VAF 42/680 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV58641281; called by muse, mutect2
- ZNF534 | c.490A>G p.S164G (on ENST00000332323 / NM_001143939.3; = p.S151G on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/334 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV56520724; called by muse, mutect2, varscan2
- ZNF536 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 147/564 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as rs1291337078, COSV62819722; called by muse, mutect2, varscan2
- ZNF571 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 18/535 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.792); catalogued as COSV60734509; called by muse, mutect2
- ZNF653 | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 138/485 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs137856645; called by muse, mutect2, varscan2
- ZPLD1 | c.146T>A p.I49N (on ENST00000466937 / NM_001329788.1; = p.I65N on NM_175056.2) | Missense Mutation (SNP) | VAF 113/407 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs563338487; called by muse, mutect2, varscan2
- A2ML1 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 94/329 reads (29%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ABCA8 | c.4719G>A p.W1573* | Nonsense Mutation (SNP) | VAF 77/470 reads (16%) | called by muse, mutect2, varscan2
- ABCC10 | c.3980C>T p.P1327L (on ENST00000372530 / NM_001198934.2; = p.P1299L on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/329 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABHD13 | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 115/338 reads (34%) | called by muse, mutect2, varscan2
- AC244197.3 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 109/570 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ADAM22 | c.2380A>C p.T794P | Missense Mutation (SNP) | VAF 72/555 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ADAMTS14 | c.2227C>T p.Q743* | Nonsense Mutation (SNP) | VAF 28/504 reads (6%) | called by muse, mutect2
- ADAMTS20 | c.1709G>A p.R570K | Missense Mutation (SNP) | VAF 119/500 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS6 | c.2282C>T p.S761F | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ADAMTSL4 | c.2641G>A p.G881R | Missense Mutation (SNP) | VAF 121/736 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ADGRB3 | c.4305G>A p.M1435I | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- AFAP1 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 19/465 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- AFF3 | c.2450C>T p.S817F | Missense Mutation (SNP) | VAF 47/265 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- AKAP9 | c.1676A>T p.N559I | Missense Mutation (SNP) | VAF 114/635 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- AKR7L | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 26/582 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ALAD | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 41/401 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- ALPK2 | c.5405G>A p.G1802E | Missense Mutation (SNP) | VAF 62/418 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALPK2 | c.3806C>T p.P1269L | Missense Mutation (SNP) | VAF 123/504 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- AMER1 | c.2813G>A p.G938E | Missense Mutation (SNP) | VAF 191/708 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD29 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 67/346 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ANKRD34B | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 146/444 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ANOS1 | c.1309C>T p.Q437* | Nonsense Mutation (SNP) | VAF 145/563 reads (26%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 31/304 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- ARHGAP31 | c.3032C>T p.S1011F | Missense Mutation (SNP) | VAF 120/548 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ARHGAP5 | c.1900C>T p.L634F | Missense Mutation (SNP) | VAF 136/580 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGEF17 | c.3614T>A p.L1205H | Missense Mutation (SNP) | VAF 56/776 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ARHGEF40 | c.1895C>T p.P632L | Missense Mutation (SNP) | VAF 54/334 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARMC4 | c.1904C>T p.P635L | Missense Mutation (SNP) | VAF 112/418 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ARMC4 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ARMCX1 | c.554G>A p.W185* | Nonsense Mutation (SNP) | VAF 119/607 reads (20%) | called by muse, mutect2, varscan2
- ASCL2 | c.413C>A p.P138Q | Missense Mutation (SNP) | VAF 67/416 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ASXL3 | c.3149G>A p.G1050E | Missense Mutation (SNP) | VAF 96/520 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATMIN | c.1921T>C p.F641L | Missense Mutation (SNP) | VAF 76/337 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATN1 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 140/632 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ATP6V1G3 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 36/317 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- ATP7B | c.2401A>G p.T801A | Missense Mutation (SNP) | VAF 44/280 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- ATP8B1 | c.1385A>T p.N462I | Missense Mutation (SNP) | VAF 37/484 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATXN2 | c.2572A>G p.K858E (on ENST00000550104; = p.K698E on NM_002973.4) | Missense Mutation (SNP) | VAF 22/456 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2
- B4GALNT3 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 83/339 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- BACH2 | c.2360C>T p.S787F | Missense Mutation (SNP) | VAF 146/479 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- BCAS1 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 61/574 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BEND2 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 148/442 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BOD1L1 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 68/359 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- C12orf40 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 114/511 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- C19orf73 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 130/594 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- C2CD2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 38/544 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2
- C3 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 90/421 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- CA4 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 36/758 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CACNA1E | c.513-1G>A p.X171_splice | Splice Site (SNP) | VAF 72/297 reads (24%) | called by muse, mutect2, varscan2
- CACNA1I | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 171/758 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CACNA2D3 | c.2371C>T p.P791S | Missense Mutation (SNP) | VAF 61/312 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA2D3 | c.2372C>T p.P791L | Missense Mutation (SNP) | VAF 63/315 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CACNG8 | c.103A>T p.M35L | Missense Mutation (SNP) | VAF 139/583 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- CADPS2 | c.2716C>T p.Q906* | Nonsense Mutation (SNP) | VAF 16/652 reads (2%) | called by muse, mutect2
- CCDC141 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 73/258 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC173 | c.165G>A p.W55* | Nonsense Mutation (SNP) | VAF 24/526 reads (5%) | called by muse, mutect2
- CCDC183 | c.716G>A p.R239K | Missense Mutation (SNP) | VAF 82/301 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- CCDC39 | c.1751C>A p.S584Y | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CCDC42 | c.621G>A p.M207I | Missense Mutation (SNP) | VAF 52/416 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC85A | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 42/410 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.027); called by muse, mutect2
- CCSER1 | c.1691G>A p.R564K | Missense Mutation (SNP) | VAF 69/296 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CD160 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 190/617 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD163L1 | c.2515G>A p.G839R | Missense Mutation (SNP) | VAF 105/420 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD300H | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 90/437 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDH17 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 71/345 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDIPT | c.522G>A p.M174I | Missense Mutation (SNP) | VAF 24/414 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- CDK14 | c.970G>A p.E324K (on ENST00000380050 / NM_001287135.2; = p.E306K on NM_012395.3) | Missense Mutation (SNP) | VAF 171/532 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEACAM18 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 134/522 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CEACAM6 | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 54/509 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- CEL | c.83C>T p.A28V (on ENST00000673714; = p.A25V on NM_001807.6) | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP290 | c.6359C>T p.S2120F | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- CEP290 | c.491G>A p.R164K | Missense Mutation (SNP) | VAF 73/296 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CFAP97 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 40/525 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- CFHR5 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 108/363 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CLCN1 | c.563-1G>A p.X188_splice | Splice Site (SNP) | VAF 18/457 reads (4%) | called by muse, mutect2
- CLDN4 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 302/778 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CNDP1 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 144/477 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CNPPD1 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 201/593 reads (34%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNPY1 | c.43+1G>A p.X15_splice | Splice Site (SNP) | VAF 164/511 reads (32%) | called by muse, mutect2, varscan2
- CNTN5 | c.225T>A p.N75K | Missense Mutation (SNP) | VAF 112/311 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL12A1 | c.8378C>A p.P2793H | Missense Mutation (SNP) | VAF 26/494 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL19A1 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 108/358 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- COL19A1 | c.2264C>T p.P755L | Missense Mutation (SNP) | VAF 103/326 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- COL25A1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 83/299 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- COL5A3 | c.4964C>T p.A1655V | Missense Mutation (SNP) | VAF 112/391 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- COL5A3 | c.3463C>T p.P1155S | Missense Mutation (SNP) | VAF 105/444 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- COL5A3 | c.1751G>A p.G584E | Missense Mutation (SNP) | VAF 98/352 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A3 | c.3251C>T p.S1084L | Missense Mutation (SNP) | VAF 144/449 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- COL6A6 | c.5504G>A p.R1835K | Missense Mutation (SNP) | VAF 132/508 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COLCA2 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 132/411 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- COX8C | c.39C>A p.H13Q | Missense Mutation (SNP) | VAF 100/529 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- COX8C | c.40T>C p.Y14H | Missense Mutation (SNP) | VAF 100/525 reads (19%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRIP3 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 46/472 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- CRTC1 | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 121/438 reads (28%) | called by muse, mutect2, varscan2
- CTNNA2 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 113/416 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CUL9 | c.3871C>T p.R1291W | Missense Mutation (SNP) | VAF 47/341 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP4Z1 | c.1231C>T p.L411F | Missense Mutation (SNP) | VAF 15/388 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYYR1 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 111/403 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DCAF12L2 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 114/624 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCHS2 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 22/708 reads (3%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); called by muse, mutect2
- DCST1 | c.689C>A p.S230Y | Missense Mutation (SNP) | VAF 42/682 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.025); called by muse, mutect2
- DENND1B | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 101/389 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DEPDC5 | c.2404C>T p.P802S (on ENST00000400246; = p.P871S on NM_014662.5) | Missense Mutation (SNP) | VAF 64/309 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DHX9 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 98/378 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DISC1 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 185/585 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- DISP2 | c.4192G>A p.G1398S | Missense Mutation (SNP) | VAF 18/404 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.509); called by muse, mutect2
- DKC1 | c.85-1G>A p.X29_splice | Splice Site (SNP) | VAF 43/316 reads (14%) | called by muse, mutect2, varscan2
- DLEC1 | c.2966C>T p.T989I | Missense Mutation (SNP) | VAF 98/448 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- DNAH11 | c.4874T>A p.F1625Y | Missense Mutation (SNP) | VAF 232/648 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DNAH6 | c.7355G>A p.G2452E | Missense Mutation (SNP) | VAF 53/408 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH6 | c.9598G>A p.D3200N | Missense Mutation (SNP) | VAF 81/333 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- DNAH6 | c.12413C>T p.S4138F | Missense Mutation (SNP) | VAF 16/397 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- DNAH8 | c.4835C>T p.S1612F | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH9 | c.10646T>C p.F3549S | Missense Mutation (SNP) | VAF 35/298 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DNM3 | c.1637G>A p.G546E (on ENST00000355305 / NM_001350206.2; = p.G536E on NM_015569.5) | Missense Mutation (SNP) | VAF 59/494 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK11 | c.3698A>G p.K1233R | Missense Mutation (SNP) | VAF 114/385 reads (30%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOCK5 | c.4453G>A p.E1485K | Missense Mutation (SNP) | VAF 28/393 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DSG2 | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 64/438 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DSG2 | c.3025C>T p.Q1009* | Nonsense Mutation (SNP) | VAF 138/549 reads (25%) | called by muse, mutect2, varscan2
- DST | c.3648G>A p.K1216= (on ENST00000361203 / NM_001374722.1; = p.K890= on NM_001723.6) | Splice Region (SNP) | VAF 60/185 reads (32%) | called by muse, mutect2, varscan2
- DTX3L | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 149/552 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- DUSP16 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 147/691 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYDC2 | c.394A>T p.M132L | Missense Mutation (SNP) | VAF 108/579 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- EARS2 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 30/621 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.221); called by muse, mutect2
- EFR3A | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ELAC1 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 39/490 reads (8%) | called by muse, mutect2
- ELOA3B | c.779A>T p.K260I | Missense Mutation (SNP) | VAF 48/1185 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- EMILIN2 | c.2492C>T p.P831L | Missense Mutation (SNP) | VAF 120/648 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- EML1 | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 15/395 reads (4%) | called by muse, mutect2
- ENAM | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 43/636 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- ENAM | c.3242C>T p.P1081L | Missense Mutation (SNP) | VAF 61/504 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ENPP4 | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENPP5 | c.62T>C p.F21S | Missense Mutation (SNP) | VAF 56/403 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- EP400 | c.2621C>T p.S874F | Missense Mutation (SNP) | VAF 82/327 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPB41L3 | c.1831C>T p.L611F | Missense Mutation (SNP) | VAF 114/618 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- EPO | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 70/472 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.618); called by muse, varscan2
- ERAL1 | c.705G>A p.M235I | Missense Mutation (SNP) | VAF 84/299 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ERLIN1 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 24/434 reads (6%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.041); called by muse, mutect2
- ERN1 | c.2527C>T p.Q843* | Nonsense Mutation (SNP) | VAF 23/382 reads (6%) | called by muse, mutect2
- ESRRB | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 102/440 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- F11 | c.1674G>A p.M558I | Missense Mutation (SNP) | VAF 116/429 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FAM171A2 | c.1229C>T p.S410F | Missense Mutation (SNP) | VAF 189/689 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- FAM184B | c.148T>C p.Y50H | Missense Mutation (SNP) | VAF 99/313 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM236D | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- FAM71A | c.1286A>T p.K429M | Missense Mutation (SNP) | VAF 213/766 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- FAM83G | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 119/441 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM83G | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 118/439 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT4 | c.9595G>A p.D3199N | Missense Mutation (SNP) | VAF 32/538 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.275); called by muse, mutect2
- FBN1 | c.5302G>A p.D1768N | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FCRL6 | c.1264C>T p.L422F | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0.025); called by muse, mutect2
- FLG | c.10880G>A p.G3627E | Missense Mutation (SNP) | VAF 248/899 reads (28%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- FLNC | c.7471C>T p.P2491S | Missense Mutation (SNP) | VAF 139/845 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- FOXR1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 24/484 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.146); called by muse, mutect2
- FRG2 | c.519A>T p.K173N | Missense Mutation (SNP) | VAF 36/710 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- FRMD7 | c.2061T>G p.D687E | Missense Mutation (SNP) | VAF 153/495 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FSCB | c.2225C>T p.P742L | Missense Mutation (SNP) | VAF 142/558 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FSIP2 | c.19293A>T p.Q6431H | Missense Mutation (SNP) | VAF 59/271 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- GAS2L1 | c.2043G>A p.M681I | Missense Mutation (SNP) | VAF 47/414 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GBP6 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 127/370 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- GLUD2 | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 109/633 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- GNA14 | c.635G>A p.W212* | Nonsense Mutation (SNP) | VAF 28/422 reads (7%) | called by muse, mutect2
- GNL1 | c.1711G>A p.D571N | Missense Mutation (SNP) | VAF 28/604 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2
- GOLGA4 | c.3094C>T p.L1032F | Missense Mutation (SNP) | VAF 21/462 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- GOLGA6L7 | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 55/304 reads (18%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- GON7 | c.101T>C p.L34S | Missense Mutation (SNP) | VAF 150/602 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- GPR161 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 69/686 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR173 | c.984G>A p.M328I | Missense Mutation (SNP) | VAF 206/754 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- GRIA1 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 24/478 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.039); called by muse, mutect2
- GRK2 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 92/457 reads (20%) | called by muse, mutect2, varscan2
- HCAR2 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 142/560 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSPA4L | c.1322A>C p.E441A | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.423); called by muse, mutect2
- HTR6 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 21/452 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- HUWE1 | c.8605G>A p.E2869K | Missense Mutation (SNP) | VAF 36/839 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); called by muse, mutect2
- HUWE1 | c.6566C>T p.S2189F | Missense Mutation (SNP) | VAF 138/467 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- HYDIN | c.9142C>T p.P3048S | Missense Mutation (SNP) | VAF 26/223 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- HYDIN | c.1561G>A p.G521R | Missense Mutation (SNP) | VAF 9/348 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); called by muse, mutect2
- IARS1 | c.305T>G p.I102S | Missense Mutation (SNP) | VAF 13/271 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- IFT172 | c.3661G>A p.G1221R | Missense Mutation (SNP) | VAF 35/428 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2
- IMPDH2 | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 21/379 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.472); called by muse, mutect2
- INPP5D | c.1715C>T p.P572L (on ENST00000445964 / NM_001017915.3; = p.P571L on NM_005541.5) | Missense Mutation (SNP) | VAF 80/453 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- IQSEC3 | c.2992G>A p.G998R (on ENST00000538872 / NM_001170738.2; = p.G695R on NM_015232.1) | Missense Mutation (SNP) | VAF 85/424 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- ITGA10 | c.2575-1G>A p.X859_splice | Splice Site (SNP) | VAF 121/405 reads (30%) | called by muse, mutect2, varscan2
- ITIH6 | c.311A>C p.K104T | Missense Mutation (SNP) | VAF 17/499 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.179); called by muse, mutect2
- KCNA10 | c.542A>T p.E181V | Missense Mutation (SNP) | VAF 86/520 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- KCNE1 | c.260G>A p.W87* | Nonsense Mutation (SNP) | VAF 31/576 reads (5%) | called by muse, mutect2
- KCNH7 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 65/455 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- KCNMA1 | c.3742G>A p.D1248N | Missense Mutation (SNP) | VAF 93/440 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- KCNQ2 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 145/587 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KCP | c.4090C>G p.P1364A (on ENST00000620378; = p.P1488A on NM_001366122.1) | Missense Mutation (SNP) | VAF 286/904 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- KDR | c.377T>A p.I126N | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- KHDC3L | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 32/620 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); called by muse, mutect2
- KIF15 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 79/308 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- KIF17 | c.1745G>A p.G582E | Missense Mutation (SNP) | VAF 158/499 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KIF20B | c.1647A>T p.E549D | Missense Mutation (SNP) | VAF 91/361 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIF5C | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 51/445 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KIRREL2 | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT tolerated (0.73); PolyPhen benign (0.014); called by muse, mutect2
- KIRREL3 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 18/262 reads (7%) | called by muse, mutect2
- KLF18 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 71/413 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- KPNA6 | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 14/401 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.21); called by muse, mutect2
- KRT14 | c.450G>A p.W150* | Nonsense Mutation (SNP) | VAF 132/459 reads (29%) | called by muse, mutect2, varscan2
- KRTAP13-1 | c.301G>C p.G101R | Missense Mutation (SNP) | VAF 35/577 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- LAGE3 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 22/616 reads (4%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.599); called by muse, mutect2
- LAMP5 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 40/508 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.192); called by muse, mutect2
- LAX1 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 13/426 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.82); called by muse, mutect2
- LGALS9B | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 59/381 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LGALS9C | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 110/220 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- LGI2 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 20/607 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- LHX2 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 39/463 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); called by muse, mutect2
- LILRA1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 52/496 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- LPCAT2 | c.1379C>T p.S460F | Missense Mutation (SNP) | VAF 62/349 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- LRP5 | c.3823C>G p.P1275A | Missense Mutation (SNP) | VAF 22/662 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- LRRC4 | c.157A>G p.S53G | Missense Mutation (SNP) | VAF 237/812 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- LRRC66 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 76/404 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- LRRC9 | c.4099C>T p.H1367Y | Missense Mutation (SNP) | VAF 14/419 reads (3%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- LRRD1 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 29/610 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.03); called by muse, mutect2
- LRRK2 | c.2116G>A p.D706N | Missense Mutation (SNP) | VAF 93/370 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LTBP2 | c.3365G>A p.G1122E | Missense Mutation (SNP) | VAF 101/441 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- LZTR1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 36/602 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2
- MAFG | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 148/574 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- MAGEA11 | c.1051C>T p.L351F | Missense Mutation (SNP) | VAF 154/653 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.106); called by muse, mutect2
- MAGEA4 | c.158A>C p.E53A | Missense Mutation (SNP) | VAF 23/522 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.959); called by muse, mutect2
- MAGEB10 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 191/649 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEB4 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 71/883 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); called by muse, mutect2
- MAGEH1 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 163/641 reads (25%) | called by muse, mutect2, varscan2
- MAN2B1 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 16/347 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2
- MAP7D1 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 56/349 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAPK8IP2 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 246/705 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MASP2 | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 161/462 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- MBTPS2 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 111/417 reads (27%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- MC3R | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 17/522 reads (3%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2
- MET | c.2575G>A p.E859K | Missense Mutation (SNP) | VAF 120/342 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MFSD5 | c.761C>T p.T254I | Missense Mutation (SNP) | VAF 154/599 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MGAT5 | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 19/381 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- MLF1 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 82/247 reads (33%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- MMP19 | c.119A>G p.K40R | Missense Mutation (SNP) | VAF 24/533 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.631); called by muse, mutect2
- MPV17L | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 112/422 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MPZL1 | c.68T>C p.V23A | Missense Mutation (SNP) | VAF 129/446 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRC1 | c.3403G>A p.D1135N | Missense Mutation (SNP) | VAF 47/504 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2
- MRC2 | c.3573G>A p.E1191= | Splice Region (SNP) | VAF 176/543 reads (32%) | called by muse, mutect2, varscan2
- MROH9 | c.1999G>T p.V667F | Missense Mutation (SNP) | VAF 136/587 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- MSLN | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 71/309 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- MST1R | c.2216C>T p.P739L | Missense Mutation (SNP) | VAF 98/462 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MT1HL1 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 107/662 reads (16%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- MTLN | c.344G>C p.R115P | Missense Mutation (SNP) | VAF 41/335 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- MUC16 | c.16432C>T p.Q5478* | Nonsense Mutation (SNP) | VAF 78/515 reads (15%) | called by muse, mutect2, varscan2
- MUC2 | c.1724C>T p.S575F | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- MXRA5 | c.7703G>A p.G2568E | Missense Mutation (SNP) | VAF 98/699 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYF5 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 121/522 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYH1 | c.3913C>T p.L1305F | Missense Mutation (SNP) | VAF 39/376 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- MYH13 | c.3738G>A p.K1246= | Splice Region (SNP) | VAF 50/290 reads (17%) | called by muse, mutect2, varscan2
- MYOZ2 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 102/412 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MYPN | c.2840T>A p.F947Y | Missense Mutation (SNP) | VAF 26/554 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- NARS2 | c.73T>G p.S25A | Missense Mutation (SNP) | VAF 148/662 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCKAP5 | c.3296C>T p.P1099L | Missense Mutation (SNP) | VAF 156/510 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NDC1 | c.2024A>G p.*675Wext*33 | Nonstop Mutation (SNP) | VAF 36/262 reads (14%) | called by muse, mutect2, varscan2
- NEB | c.6183+1G>C p.X2061_splice | Splice Site (SNP) | VAF 62/240 reads (26%) | called by muse, mutect2, varscan2
- NEBL | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 22/351 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- NEK5 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 74/230 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEURL3 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 20/503 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- NHS | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 177/621 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NINL | c.3353G>A p.R1118K | Missense Mutation (SNP) | VAF 92/374 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- NINL | c.3352A>T p.R1118W | Missense Mutation (SNP) | VAF 92/375 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- NLGN4X | c.755G>C p.G252A | Missense Mutation (SNP) | VAF 159/728 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP4 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 125/550 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- NLRP8 | c.1168T>C p.F390L | Missense Mutation (SNP) | VAF 116/407 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- NOL4 | c.1715C>T p.S572F | Missense Mutation (SNP) | VAF 55/272 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- NOP9 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 80/452 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- NPRL3 | c.1037C>T p.S346F (on ENST00000611875 / NM_001077350.3; = p.S321F on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/213 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NPY1R | c.352T>A p.F118I | Missense Mutation (SNP) | VAF 25/660 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2
- NRAP | c.1726G>A p.E576K (on ENST00000359988 / NM_001322945.2; = p.E541K on NM_006175.4) | Missense Mutation (SNP) | VAF 86/376 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- NRCAM | c.2593C>T p.H865Y (on ENST00000379028 / NM_001371124.1; = p.H849Y on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 269/810 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- NSMCE4A | c.1048C>T p.Q350* | Nonsense Mutation (SNP) | VAF 92/399 reads (23%) | called by muse, mutect2, varscan2
- NUP153 | c.3803C>T p.T1268I | Missense Mutation (SNP) | VAF 134/484 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- OBSCN | c.7528C>A p.P2510T | Missense Mutation (SNP) | VAF 134/636 reads (21%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.602); called by muse, varscan2
761 further variants in this file (205 protein-altering or splice-affecting, 498 silent, 58 other) are not listed here.
